Surgical pathology report (de-identified scan), TCGA case TCGA-24-2254, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2254-01A (Primary Tumor).

[page 1 of 4]
TCGA-24-2254

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY (INCLUDING FS1)
- PAPILLARY SEROUS ADENOCARCINOMA, WITH ENDOMETRIOID AREAS, POORLY
DIFFERENTIATED (12 CM IN GREATEST DIMENSION) (SEE SYNOPSIS)
FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- NO EVIDENCE OF MALIGNANCY
OVARY, LEFT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, WITH ENDOMETRIOID AREAS, POORLY
DIFFERENTIATED (6.0 CM IN GREATEST DIMENSION)
FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- PERITUBAL SOFT TISSUE IS INVOLVED BY ADENOCARCINOMA
BLADDER, WALL AND PERIVESICAL SOFT TISSUE, EXCISION
- INVASIVE IMPLANTS OF PAPILLARY SEROUS ADENOCARCINOMA
OMENTUM, OMENTECTOMY
- EXTENSIVE INVASIVE IMPLANTS OF PAPILLARY SEROUS ADENOCARCINOMA
UTERUS, SEROSAL SURFACE, TOTAL ABDOMINAL HYSTERECTOMY
- INVASIVE PAPILLARY SEROUS ADENOCARCINOMA IMPLANTS
UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA INVOLVEMENT, BY DIRECT EXTENSION FROM
SEROSAL IMPLANTS
- EXTENSIVE LYMPH-VASCULAR INVASION BY CARCINOMA IDENTIFIED
- LEIOMYOMA (3.8 CM IN GREATEST DIMENSION)
UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- NO EVIDENCE OF MALIGNANCY

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides (and/or other material indicated in the
diagnosis).

***Report Electronically Reviewed and Signed Out By

[page 2 of 4]
[REDACTED]

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pickup for frozen section 'right ovary,' consisting of a 360 gram, 12 x 10 x 7 cm ovary with shiny, smooth lobulated external surface with a 7.5 x 4.5 cm irregular and granular area of apparent rupture with tan soft tumor projecting through. The ovary is bisected to show a cystic mass with >75% of the lumen filled with tan, fleshy, soft tumor. Two areas are sampled as FS1. Tumor taken for tumor bank. Rest for permanents," by [REDACTED].

FS1: Ovary, right, oophorectomy

- "Papillary serous adenocarcinoma," by [REDACTED]

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis. [REDACTED]

History:

The patient is a [REDACTED] with ovarian mass and with widespread metastatic disease and mildly elevated CEA. Operative procedure: Exploratory laparotomy with total abdominal hysterectomy, bilateral salpingo-oophorectomy and abdominal tumor debulking and omentectomy.

Specimen(s) Received:

- A: RIGHT OVARY
- B: LEFT ADNEXA
- C: BLADDER TUMOR
- D: ABDOMINAL TUMOR AND OMENTUM
- E: UTERUS

Gross Description

The specimens are received in five formalin-filled containers, each labeled [REDACTED]. The first container is labeled "right ovary, FS1/X." It contains a previously bisected 360 gram tan-yellow ovarian mass. The mass measures 12 x 10 x 7 cm. The serosal surface shows numerous bosselations. Focally, the capsule is ruptured and at this site the tumor is seen projecting to the exterior. Also identified on the ovarian surface is a possible fallopian tube measuring 4.5 cm in length and has a luminal diameter of 0.3 cm. The fallopian tube grossly appears uninvolved. Further sectioning of the ovarian mass shows a tan-yellow firm tumor mass which is solid in most part, but focally shows cystic change and the inner surface of the cyst wall shows papillary tan-white projections. Labeled A1 - possible right fallopian tube; A2 to A11 - sections through the right ovarian tumor. [REDACTED]-----.

The second container is labeled "left adnexa." It contains portions of fallopian tube and with attached tan-yellow ovarian mass. The fallopian tube measures 3.0 x 1.1 x 0.8 cm, and the attached ovarian mass measures 6.0 x 6.5 x 4.0 cm. The mass weighs 60.5 grams. Sections through the fallopian tube show portions of the serosal surface involved by the tumor, however, the mucosa appears uninvolved. Part of the ovarian surface appears ragged, while part of the ovarian surface is smooth and shows multiple tan-yellow papillary excrescences on the surface. Based on the gross examination, it is not possible to discern the primary site of the tumor (left ovary vs right ovary). Further sectioning of the ovary reveals multiple nodular tan-yellow solid and papillary tumors with focal areas of necrosis. Labeled B1 - sections through the fallopian tube with the tumor at the serosal aspect; B2 to B8 - random sections through the ovarian tumor. [REDACTED]

The third container is labeled "bladder." It contains three tan-yellow to tan-pink fat and soft tissue fragments ranging from 2.0 to 5.0 cm in greatest

[page 3 of 4]
dimensions and 5.0 x 5.0 x 2.0 cm in aggregate. Sections show multiple tan-white to tan-pink nodules consistent with the primary tumor in the ovaries. Labeled C1 to C3.

The fourth container is labeled "abdominal tumor and omentum." It contains multiple tan-yellow to tan-pink fatty tissue fragments consistent with portions of omentum. The fragments range from 4.0 to 10.0 cm in greatest dimensions, and 15.0 x 13.0 x 6.0 cm in aggregate. The largest fragment shows multiple tan-white nodules that are matted together to form the omental cake. Sections of the mass show tan-white nodular tumor masses dissecting into the omental stroma. Labeled D1 to D4.

The fifth container is labeled "uterus." It contains a uterus and cervix weighing 165 grams, and measuring 10.0 x 8.0 x 7.0 cm. The uterus is bivalved when received. The serosal surface is tan-pink and shows multiple tan-yellow nodules with consistency and cut surface similar to the lesions noted in both the ovaries, and is grossly consistent for serosal implants. The serosal implants range from 0.6 to 4.0 cm in greatest dimensions. The uterus is further sectioned to show a 2.5 cm unremarkable endocervical canal. The endometrial cavity measures 3.5 x 2.2 cm. A fundal, calcified intramural leiomyoma is identified and measures 3.8 cm in greatest dimensions. The endometrial cavity is unremarkable, and does not show any involvement by the ovarian tumor. Labeled E1 - posterior cervix with endocervical canal; E2 - posterior lower uterine segment; E3 - possible posterior endometrium; E4 - myometrium with adjoining serosal tumor implant; E5 - anterior cervix with endocervical canal; E6 - possible anterior lower uterine segment; E7 - possible anterior endometrium; E8 and E9 - sections through the serosal implant invading into the outer one-third of the myometrium; E10 - section through the leiomyoma. Jar 2.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. The HISTOLOGIC DIAGNOSIS is:

Serous adenocarcinoma with endometrial areas.

2. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:

Right and left ovaries (synchronous primary tumors).

3. HISTOLOGIC GRADE (G):

G3-4 (Poorly differentiated or undifferentiated)

4. Tumor IS NOT identified on the ovarian surface(s).

5. Metastatic involvement of the omentum is PRESENT.

6. The maximum dimension of tumor implants outside the true pelvis is:

> 2 cm

7. Regional lymph node metastases CANNOT BE EVALUATED.

8. The total number of regional lymph nodes examined is 0.

10. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	Macroscopic
T3c	IIIC		
peritoneal metastasis beyond		true	
pelvis measuring > 2 cm in greatest		dimension.	

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

[page 4 of 4]
MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS:

AJCC/UICC/FIGO

IIIC

(T3c/NX/MX)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file fc03dbe4-13fb-4fc3-a4c8-fd6e2aba613a (TCGA-24-2254.3788629F-17DA-4075-AF61-CF124BDFB48E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).